Somatic mutation profile of tumor specimen TCGA-D6-A6EO-01A (aliquot TCGA-D6-A6EO-01A-11D-A31L-08) from TCGA case TCGA-D6-A6EO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 44.3 years (16,185 days).
Specimen TCGA-D6-A6EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9cb1d9c-c9e1-4342-aff5-9cda0e596bdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EO-10A (Blood Derived Normal), aliquot TCGA-D6-A6EO-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5038e0f0-7908-4634-8cb7-4407af2035ae

The open-access MAF lists 90 somatic variants for this specimen: 71 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs146861278, COSV54633255; called by muse, mutect2, varscan2
- ADGRB1 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100030176; called by muse, mutect2, varscan2
- ADGRL4 | c.1040T>C p.L347S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100876422; called by muse, mutect2, varscan2
- ANKRD17 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429791; called by muse, mutect2, varscan2
- ATAD2 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV99785133; called by muse, mutect2, varscan2
- AZIN1 | c.946A>G p.M316V | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV100457727; called by muse, mutect2, varscan2
- BBX | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100362118; called by muse, mutect2, varscan2
- BDP1 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs971820039, COSV100703407; called by muse, mutect2, varscan2
- C1orf159 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as rs747620747, COSV99618776; called by muse, varscan2
- CAMK2D | c.761C>G p.T254S | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99594578; called by muse, mutect2, varscan2
- CAPRIN2 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99195602; called by muse, mutect2, varscan2
- CARD6 | c.3014C>G p.S1005C | Missense Mutation (SNP) | VAF 166/863 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV54564475, COSV99621144; called by muse, mutect2, varscan2
- CDC5L | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101015148; called by muse, mutect2, varscan2
- CELSR1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs761384265, COSV99419560; called by muse, mutect2, varscan2
- DAPK1 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100802570; called by muse, mutect2, varscan2
- DNAH9 | c.12151C>T p.L4051F | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99307424; called by muse, mutect2, varscan2
- DNHD1 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99600746; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 105/154 reads (68%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.02); catalogued as rs1484689810, COSV99143732; called by muse, mutect2, varscan2
- ERC2 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV99888203; called by muse, mutect2, varscan2
- ESAM | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1178148036, COSV99632046; called by muse, mutect2, varscan2
- FNBP4 | c.1856C>A p.S619* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as COSV55451906, COSV99771337, COSV99771900; called by muse, mutect2, varscan2
- GIMAP6 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV100188349; called by muse, mutect2, varscan2
- GIMAP6 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100188350, COSV100188366; called by muse, mutect2, varscan2
- GRIA2 | c.2237G>T p.G746V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645544; called by muse, mutect2, varscan2
- GRIK5 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53481910; called by muse, mutect2, varscan2
- GZF1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100582637; called by muse, mutect2, varscan2
- HAO1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1213525405, COSV101113287; called by muse, mutect2, varscan2
- HEATR5A | c.1613C>G p.A538G | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV101120418; called by muse, mutect2, varscan2
- HIVEP3 | c.2820G>T p.L940F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.207); catalogued as COSV56023611, COSV56026165; called by muse, mutect2
- HSD3B7 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs779937999, COSV52681366; called by muse, mutect2, varscan2
- IFI44 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1409648728, COSV100877257; called by muse, mutect2, varscan2
- IL12RB2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as rs765878513, COSV52023426; called by muse, mutect2, varscan2
- KANSL3 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100831229; called by muse, mutect2, varscan2
- LRRK2 | c.5953C>G p.L1985V | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100110935, COSV54149833; called by muse, mutect2, varscan2
- MAVS | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100816371; called by muse, mutect2, varscan2
- MDC1 | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV100903028; called by muse, mutect2, varscan2
- MSI1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs538550275, COSV57456129; called by muse, varscan2
- MYT1L | c.1000T>G p.C334G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101221227; called by muse, mutect2, varscan2
- ONECUT3 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101210693; called by muse, mutect2, varscan2
- OR4C46 | c.604G>T p.G202* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100060902; called by muse, mutect2, varscan2
- OR5AS1 | c.150T>A p.N50K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as COSV100546352; called by muse, mutect2, varscan2
- OR9Q1 | c.22T>G p.L8V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100110372; called by muse, mutect2, varscan2
- PAPPA2 | c.4213G>A p.D1405N | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.304); catalogued as rs1246341501, COSV100868475; called by muse, mutect2, varscan2
- PCDH15 | c.5081C>T p.A1694V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.071); catalogued as COSV100225757; called by muse, mutect2, varscan2
- PHF3 | c.5548A>T p.N1850Y | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100013789; called by muse, mutect2, varscan2
- PLEKHG7 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs749423311, COSV101188841, COSV101188874; called by muse, mutect2, varscan2
- PON3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs367854595, COSV55698289; called by muse, mutect2, varscan2
- PTCH1 | c.2578_2579insT p.D860Vfs*3 | Frame Shift Ins (INS) | VAF 67/128 reads (52%) | catalogued as COSV100109612; called by mutect2, pindel, varscan2
- PTPRZ1 | c.5542G>C p.E1848Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV101100652; called by muse, mutect2, varscan2
- PUM1 | c.1197G>C p.L399F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); catalogued as COSV99928747; called by muse, mutect2, varscan2
- RAP1GDS1 | c.613G>T p.A205S (on ENST00000408927 / NM_001100427.2; = p.A206S on NM_021159.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99217259; called by muse, mutect2, varscan2
- RBM43 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.117); catalogued as COSV100508631; called by muse, mutect2, varscan2
- REG3A | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100532866; called by muse, mutect2, varscan2
- SIK3 | c.1077G>A p.Q359= (on ENST00000445177 / NM_001366686.2; = p.Q365= on NM_025164.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99408617; called by muse, mutect2, varscan2
- SLC22A2 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100871022; called by muse, mutect2, varscan2
- SLCO2A1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200244112, COSV100189232; called by muse, mutect2
- SMARCAD1 | c.1272G>C p.W424C | Missense Mutation (SNP) | VAF 126/162 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100759013; called by muse, mutect2, varscan2
- SRCAP | c.6353C>T p.T2118I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99351033; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | PolyPhen benign (0.141); catalogued as rs768924800, COSV100602979; called by muse, mutect2, varscan2
- TAOK1 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99914571; called by muse, mutect2, varscan2
- TNPO2 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100790397; called by muse, mutect2, varscan2
- VNN1 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100907810; called by muse, mutect2, varscan2
- WWC2 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767478435, COSV100968511; called by muse, mutect2, varscan2
- XIRP2 | c.1128C>A p.D376E (on ENST00000628543; = p.D551E on NM_152381.6) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.45); catalogued as COSV99746188; called by muse, mutect2, varscan2
- YARS2 | c.1078C>G p.R360G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as CM1312741, COSV61401564, COSV61401718; called by muse, mutect2, varscan2
- ZFYVE9 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV55096943, COSV99820546; called by muse, mutect2, varscan2
- ZNF347 | c.1180A>T p.T394S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100498388; called by muse, mutect2, varscan2
- ZPLD1 | c.107C>A p.A36D (on ENST00000466937 / NM_001329788.1; = p.A52D on NM_175056.2) | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100083465; called by muse, mutect2, varscan2
- ZXDC | c.2113G>A p.G705S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60445795; called by muse, mutect2, varscan2
- NSD1 | c.6085del p.T2029Hfs*6 | Frame Shift Del (DEL) | VAF 54/114 reads (47%) | called by mutect2, pindel, varscan2
- TP53 | c.572_587del p.P191Qfs*51 | Frame Shift Del (DEL) | VAF 28/45 reads (62%) | called by mutect2, pindel, varscan2
- ATN1 | c.1707T>A p.S569= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as COSV100755917; called by muse, mutect2, varscan2
- CTTNBP2 | c.2794T>C p.L932= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV99354607; called by muse, mutect2, varscan2
- ESR1 | c.537C>A p.A179= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99240573; called by muse, mutect2, varscan2
- LDB2 | c.504A>G p.L168= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV100454512; called by muse, mutect2, varscan2
- NCAN | c.352C>A p.R118= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99388038; called by muse, mutect2, varscan2
- NLRC3 | c.2590C>T p.L864= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- OR2H1 | c.69G>A p.R23= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as COSV101009901; called by muse, mutect2, varscan2
- OR52W1 | c.420G>T p.L140= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100258712; called by muse, mutect2, varscan2
- PAFAH1B2 | c.615C>T p.I205= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs758532200, COSV59167852; called by muse, mutect2, varscan2
- PXDN | c.2904C>T p.I968= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs781271519, COSV99414548; called by muse, mutect2, varscan2
- RNF214 | c.897G>A p.E299= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs1436774139, COSV100326888; called by muse, mutect2, varscan2
- SALL2 | c.2814G>A p.P938= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs530697143, COSV100444547; called by muse, mutect2, varscan2
- SMCHD1 | c.2421A>G p.R807= | Silent (SNP) | VAF 30/360 reads (8%) | catalogued as COSV99862300; called by muse, mutect2
- STAG2 | c.1542A>G p.T514= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- TMEM39A | c.666G>A p.E222= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100052603; called by muse, mutect2, varscan2
- TMPRSS15 | c.2349A>G p.P783= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as rs746126429, COSV99518907; called by muse, mutect2, varscan2
- TRABD2A | c.861C>T p.I287= (on ENST00000409520 / NM_001277053.2; = p.I238= on NM_001080824.3) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100120160; called by muse, mutect2, varscan2
- ZSCAN10 | c.735G>A p.P245= (on ENST00000252463; = p.P300= on NM_032805.3) | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV52966951, COSV99373853; called by muse, mutect2, varscan2
- NFYC | c.387+1162A>T | Intron (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100438661; called by muse, mutect2, varscan2
